Somatic mutation profile of tumor specimen C3N-02030-01 (aliquot CPT0133760076) from CPTAC case C3N-02030, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.7 years (22,893 days).
Specimen C3N-02030-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86cd73db-5847-44f8-9038-93f7eb7bde2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02030-71 (Blood Derived Normal), aliquot CPT0133880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79bab46e-6ad6-4574-aeb5-356ba058b17d

The open-access MAF lists 657 somatic variants for this specimen: 450 protein-altering or splice-affecting, 130 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 305, Silent 130, Frame Shift Del 79, Intron 47, Frame Shift Ins 26, Nonsense Mutation 23, 3'UTR 10, 5'UTR 8, Splice Site 8, RNA 5, In Frame Del 5, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 146/397 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 73/124 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.26dup p.A11Sfs*78 | Frame Shift Ins (INS) | VAF 160/482 reads (33%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189del p.E64Rfs*25 | Frame Shift Del (DEL) | VAF 160/458 reads (35%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PRPF6 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs387907100, CM112959, COSV53868700; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 62/202 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 185/403 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TECTA | c.5977C>T p.R1993* | Nonsense Mutation (SNP) | VAF 114/329 reads (35%) | catalogued as rs760574657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USP9X | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 34/129 reads (26%) | catalogued as rs1555924860, COSV100199662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs755655007, COSV99367987; called by muse, mutect2, varscan2
- ABCA8 | c.4036G>A p.V1346M | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767871494, COSV52201017; called by muse, mutect2, varscan2
- ABCB9 | c.1672del p.L558Wfs*24 (on ENST00000280560 / NM_019625.4; = p.L515Wfs*24 on NM_019624.3) | Frame Shift Del (DEL) | VAF 68/215 reads (32%) | catalogued as rs1334723787; called by mutect2, pindel, varscan2
- ABCC1 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 77/216 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756648375; called by muse, mutect2, varscan2
- ADAMTS16 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484616740, COSV56997505; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 177/292 reads (61%) | catalogued as rs748399150; called by mutect2, pindel, varscan2
- AHCY | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); catalogued as rs1277245330; called by muse, mutect2
- AKAP8 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs537526016; called by muse, mutect2, varscan2
- AKAP9 | c.116dup p.R40Efs*7 | Frame Shift Ins (INS) | VAF 90/260 reads (35%) | catalogued as rs765201611; called by mutect2, varscan2
- ALDH7A1 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 156/406 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as CM121731; called by muse, mutect2, varscan2
- ANTXR1 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 24/241 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV58011851; called by muse, mutect2, varscan2
- AOX1 | c.1666C>A p.L556I | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs769661664; called by muse, mutect2, varscan2
- AP1G2 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as COSV55337826; called by muse, mutect2
- APOA5 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 250/705 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM120394; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 160/415 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 104/276 reads (38%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GAT1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763308287; called by muse, mutect2, varscan2
- BDH1 | c.83+2T>C p.X28_splice | Splice Site (SNP) | VAF 7/160 reads (4%) | catalogued as COSV64018600; called by muse, mutect2
- BMPR1B | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373000965; called by muse, mutect2, varscan2
- BRD2 | c.1932C>A p.Y644* | Nonsense Mutation (SNP) | VAF 137/336 reads (41%) | catalogued as COSV100875888; called by muse, mutect2, varscan2
- CACFD1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs782532821; called by muse, mutect2
- CACNB1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs753711036; called by muse, mutect2, varscan2
- CACYBP | c.432del p.V145Sfs*22 | Frame Shift Del (DEL) | VAF 17/149 reads (11%) | catalogued as rs1161545619; called by mutect2, pindel, varscan2
- CCDC190 | c.300G>T p.Q100H | Missense Mutation (SNP) | VAF 116/491 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373634463; called by muse, mutect2, varscan2
- CDIP1 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 11/311 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs767541693; called by muse, mutect2
- CEBPA | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 276/717 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781549846; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 40/133 reads (30%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CFAP206 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1333669635; called by muse, mutect2
- CLDN12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 137/390 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV55307631; called by muse, mutect2, varscan2
- CNTLN | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs992395185; called by muse, mutect2
- CNTN4 | c.2047G>A p.G683R | Missense Mutation (SNP) | VAF 63/599 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329114875, COSV61872600; called by muse, mutect2, varscan2
- COG5 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 28/471 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs755030238, COSV51744556; ClinVar: uncertain significance; called by muse, mutect2
- COL14A1 | c.1321+1G>A p.X441_splice | Splice Site (SNP) | VAF 41/103 reads (40%) | catalogued as rs775204866, COSV52852671; called by muse, mutect2, varscan2
- COL27A1 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs781277879, COSV61925278; called by muse, mutect2
- COL3A1 | c.2834G>T p.G945V | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100483108; called by muse, mutect2
- COL7A1 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 188/554 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778104401; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CPAMD8 | c.1994C>T p.A665V (on ENST00000651564; = p.A618V on NM_015692.5) | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV52234755; called by muse, mutect2, varscan2
- CPSF6 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs753465837; called by muse, mutect2, varscan2
- CPTP | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 66/825 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1348947469; called by muse, mutect2
- CREM | c.364A>G p.R122G (on ENST00000429130; = p.R73G on NM_001881.3) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188189426; called by muse, mutect2
- CRISPLD2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 131/372 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs372363505; called by muse, mutect2, varscan2
- CSMD1 | c.9422G>A p.R3141H (on ENST00000520002; = p.R3140H on NM_033225.6) | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs768149539, COSV59277588; called by muse, mutect2, varscan2
- D2HGDH | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1472114573, COSV58319342; called by muse, mutect2, varscan2
- DBH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 201/478 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs199566547; called by muse, mutect2, varscan2
- DCHS1 | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 217/462 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs772193454; called by muse, mutect2, varscan2
- DDX43 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64812146; called by muse, mutect2
- DKK4 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs764520274, COSV55183577; called by muse, mutect2, varscan2
- DLEC1 | c.3314C>T p.A1105V | Missense Mutation (SNP) | VAF 143/392 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs780446743, COSV57300501; called by muse, mutect2, varscan2
- DLG2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs1188456228; called by muse, mutect2
- DMBT1 | c.7462C>T p.R2488C (on ENST00000338354 / NM_001377530.1; = p.R1731C on NM_004406.3) | Missense Mutation (SNP) | VAF 192/695 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs1437407547; called by muse, mutect2, varscan2
- DNAH2 | c.2151G>T p.W717C | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66720905; called by muse, mutect2
- DOCK5 | c.966del p.F322Lfs*5 | Frame Shift Del (DEL) | VAF 54/144 reads (38%) | catalogued as rs36119599; called by mutect2, pindel, varscan2
- DRC3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs757392054; called by muse, mutect2, varscan2
- DSCAM | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs367647810, COSV101259937; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- EML3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1465554218; called by muse, mutect2
- EP400 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200859619; called by muse, mutect2, varscan2
- EPHA6 | c.2426G>A p.S809N (on ENST00000389672 / NM_001080448.3; = p.S201N on NM_173655.4) | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.158); catalogued as rs774943115; called by muse, mutect2
- ERI3 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64833919; called by muse, mutect2
- FAM131B | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 185/526 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs759366087, COSV58367322, COSV58375458; called by muse, mutect2, varscan2
- FAM185A | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); catalogued as COSV68643796; called by muse, mutect2
- FAM186A | c.5432C>T p.A1811V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs765273273; called by muse, mutect2, varscan2
- FEV | c.704dup p.H236Pfs*18 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs141171754; called by mutect2, pindel, varscan2
- FKBP8 | c.779C>T p.T260M (on ENST00000222308 / NM_001308373.2; = p.T261M on NM_012181.5) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV55893476; called by muse, mutect2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 294/806 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC2 | c.275_277del p.K92del | In Frame Del (DEL) | VAF 294/925 reads (32%) | catalogued as rs1203250715; called by pindel, varscan2
- FOXD3 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.074); catalogued as rs943720041; called by muse, mutect2, varscan2
- FRMPD4 | c.3313del p.S1105Vfs*3 | Frame Shift Del (DEL) | VAF 106/339 reads (31%) | catalogued as rs35659462; called by mutect2, pindel, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 40/140 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1394891575; called by muse, mutect2, varscan2
- GPAT2 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752511500; called by muse, mutect2, varscan2
- GPR137B | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 81/485 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs147078955; called by muse, mutect2, varscan2
- GPR75 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs144824328; called by muse, mutect2, varscan2
- HNRNPA1 | c.18T>G p.S6= | Splice Region (SNP) | VAF 36/98 reads (37%) | catalogued as rs755898648; called by muse, mutect2, varscan2
- HSPA12A | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781809567; called by muse, mutect2, varscan2
- INPP4A | c.2930C>T p.T977M (on ENST00000074304 / NM_001134224.1; = p.T938M on NM_004027.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1559132688, COSV50789938; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 36/125 reads (29%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- ITGB6 | c.2330G>A p.R777K | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51791808, COSV51798615; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 40/94 reads (43%) | catalogued as rs755650243; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 77/246 reads (31%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KDM6A | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65040820; called by muse, mutect2, varscan2
- KHDC1 | c.581G>A p.S194N (on ENST00000370384 / NM_001251874.2; = p.S121N on NM_030568.5) | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.916); catalogued as rs962762004, COSV57615383; called by muse, mutect2, varscan2
- KIAA1586 | c.619del p.I207Lfs*17 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs746314511; called by mutect2, varscan2
- KLHL26 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.351); catalogued as rs749078539; called by muse, mutect2, varscan2
- KMT2B | c.7030G>A p.A2344T | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755245377; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KMT2D | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56468464; called by muse, varscan2
- KMT5B | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 11/282 reads (4%) | catalogued as COSV58563836; called by muse, mutect2
- LAGE3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV62074504; called by muse, mutect2, varscan2
- LANCL2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 180/512 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.487); catalogued as rs770121457, COSV54649883; called by muse, mutect2, varscan2
- LILRB5 | c.1526G>A p.G509D (on ENST00000449561 / NM_001081442.3; = p.G508D on NM_006840.5) | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as COSV60260780; called by muse, mutect2, varscan2
- LMTK3 | c.2190dup p.E731Rfs*809 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs1555901294; called by mutect2, varscan2
- LTB | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs567302751, COSV53000420; called by muse, mutect2
- MAGIX | c.958dup p.A320Gfs*88 | Frame Shift Ins (INS) | VAF 80/239 reads (33%) | catalogued as rs1321319432; called by mutect2, pindel
- MAML3 | c.2426A>G p.Q809R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1171552463; called by muse, varscan2
- MAN2C1 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 138/344 reads (40%) | catalogued as COSV99145269; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 28/297 reads (9%) | catalogued as rs745558596; called by mutect2, pindel
- MRC2 | c.1412C>A p.P471H | Missense Mutation (SNP) | VAF 138/394 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640762; called by muse, mutect2, varscan2
- MTERF3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs750850029; called by muse, mutect2, varscan2
- MTHFD1L | c.2177T>C p.I726T | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104426664; called by muse, mutect2
- MYLK | c.4813G>T p.D1605Y | Missense Mutation (SNP) | VAF 197/587 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60610051; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 41/202 reads (20%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFX1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 59/178 reads (33%) | catalogued as rs1451971621; called by muse, mutect2, varscan2
- NOTCH1 | c.3179T>C p.V1060A | Missense Mutation (SNP) | VAF 202/593 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53082811; called by muse, mutect2, varscan2
- NOTCH2 | c.3896G>A p.R1299Q | Missense Mutation (SNP) | VAF 42/547 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.886); catalogued as rs773971657, COSV99867000; called by muse, mutect2
- NRROS | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751058757, COSV60744792; called by muse, mutect2, varscan2
- OCA2 | c.2451G>T p.M817I | Missense Mutation (SNP) | VAF 26/600 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV62352319; called by muse, mutect2
- ODF3L2 | c.49dup p.L17Pfs*62 | Frame Shift Ins (INS) | VAF 38/123 reads (31%) | catalogued as rs748636054; called by mutect2, pindel, varscan2
- OGA | c.1578del p.M527Cfs*27 | Frame Shift Del (DEL) | VAF 118/487 reads (24%) | catalogued as COSV63382218; called by mutect2, pindel, varscan2
- OGFOD3 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 109/334 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs756501679, COSV57339492; called by muse, mutect2, varscan2
- OR12D2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs752585138, COSV65828725; called by muse, mutect2
- OR13G1 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1558292655; called by muse, mutect2, varscan2
- OR2A12 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 147/465 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs749726901, COSV68822033; called by muse, mutect2, varscan2
- OR2T3 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 16/546 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs1425555169; called by muse, mutect2
- OR52D1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 138/359 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760829167, COSV59487388; called by muse, mutect2, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OR6C4 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs750194566; called by muse, mutect2, varscan2
- OTUD7B | c.1976del p.G659Vfs*169 | Frame Shift Del (DEL) | VAF 49/268 reads (18%) | catalogued as COSV100967422; called by mutect2, pindel, varscan2
- PARD3B | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV62502529; called by muse, mutect2, varscan2
- PAX5 | c.76dup p.V26Gfs*49 | Frame Shift Ins (INS) | VAF 34/142 reads (24%) | catalogued as rs767894241; called by mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 42/111 reads (38%) | catalogued as rs753190856; called by mutect2, varscan2
- PBRM1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs115997236; called by muse, mutect2, varscan2
- PCDHA5 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 164/426 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.232); catalogued as COSV65352687, COSV65353320, COSV65354029; called by muse, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | catalogued as rs1262793592; called by mutect2, pindel, varscan2
- PDE2A | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs138870390, COSV57811844; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | catalogued as rs759495724; called by mutect2, varscan2
- PGAP6 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 111/372 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758802749; called by muse, mutect2
- PHACTR4 | c.2032G>T p.E678* (on ENST00000373839 / NM_001350159.2; = p.E688* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 41/143 reads (29%) | catalogued as COSV65783415, COSV65785417; called by muse, mutect2, varscan2
- PI4KA | c.5219A>G p.K1740R | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs1390556648, COSV55402756; called by muse, mutect2
- PI4KA | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1460046498, COSV55412316, COSV55422086; called by muse, mutect2, varscan2
- PIAS4 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs765883460; called by muse, mutect2, varscan2
- PIK3C2B | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs373236355; called by muse, mutect2, varscan2
- PKP3 | c.2260_2262del p.K754del | In Frame Del (DEL) | VAF 42/142 reads (30%) | catalogued as rs755089774; called by pindel, varscan2
- PLEKHM1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 90/300 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251964349, COSV69598825; called by mutect2, varscan2
- PMFBP1 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.528); catalogued as rs1480138422; called by muse, mutect2, varscan2
- POLD1 | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs1060501855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); catalogued as COSV99605417; called by muse, mutect2
- POLM | c.275dup p.C94Lfs*77 | Frame Shift Ins (INS) | VAF 19/185 reads (10%) | catalogued as rs1562673451; called by mutect2, pindel, varscan2
- POLR3GL | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370170498; called by muse, mutect2
- PPP4R2 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1230961376; called by muse, mutect2, varscan2
- PPP4R3B | c.1478del p.L493* | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs749912209; called by mutect2, varscan2
- PRDM13 | c.1869C>A p.H623Q | Missense Mutation (SNP) | VAF 301/777 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375460946; called by muse, mutect2, varscan2
- PTH1R | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 237/665 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752454624, COSV57315208; called by muse, mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 41/164 reads (25%) | catalogued as rs1234606471; called by mutect2, varscan2
- R3HCC1 | c.538C>T p.P180S (on ENST00000411463; = p.P140S on NM_001136108.3) | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1563178614; called by muse, mutect2
- RASSF4 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.065); catalogued as rs748139811; called by muse, mutect2, varscan2
- RDH11 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 103/235 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.269); catalogued as rs563954790, COSV101191426; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as rs751982308; called by mutect2, varscan2
- RNF39 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.94); PolyPhen benign (0.134); catalogued as rs773266930; called by muse, mutect2, varscan2
- RPL7L1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100491742; called by muse, mutect2, varscan2
- RUSF1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs368993746; called by muse, mutect2
- RXFP1 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs776423555; called by muse, mutect2, varscan2
- SALL2 | c.1586del p.P529Qfs*22 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | catalogued as rs755171367; called by mutect2, pindel, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs763290832; called by mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs1270083658; called by mutect2, pindel
- SEC24C | c.1375del p.Q459Sfs*32 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | catalogued as rs764652839; called by mutect2, pindel, varscan2
- SIGLEC12 | c.622C>A p.P208T (on ENST00000291707 / NM_053003.4; = p.P90T on NM_033329.2) | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52463588; called by muse, mutect2, varscan2
- SIPA1 | c.748_750del p.K250del | In Frame Del (DEL) | VAF 43/111 reads (39%) | catalogued as rs1333397145; called by mutect2, pindel, varscan2
- SKIV2L | c.1637del p.G546Afs*83 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as COSV64814087; called by mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 74/326 reads (23%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC2A11 | c.895G>A p.V299M (on ENST00000345044 / NM_001024938.4; = p.V306M on NM_030807.5) | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs773866178; called by muse, mutect2, varscan2
- SLC43A2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as rs746970383; called by muse, mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 69/300 reads (23%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SPATA20 | c.1933G>A p.A645T (on ENST00000356488 / NM_001258372.1; = p.A661T on NM_022827.4) | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs990340844, COSV50067203; called by muse, mutect2
- SPATC1L | c.580C>T p.R194C (on ENST00000291672 / NM_001142854.2; = p.R40C on NM_032261.5) | Missense Mutation (SNP) | VAF 109/322 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs751537273; called by muse, mutect2, varscan2
- SPEF2 | c.877dup p.I293Nfs*6 | Frame Shift Ins (INS) | VAF 45/195 reads (23%) | catalogued as rs1390109415; called by mutect2, varscan2
- SPEN | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 200/524 reads (38%) | catalogued as rs1307834195, COSV65365281; called by muse, mutect2, varscan2
- SPEN | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); catalogued as rs763959899, COSV65359777; called by muse, mutect2, varscan2
- SPSB4 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776085694, COSV60150454; called by muse, mutect2, varscan2
- SPTA1 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 171/796 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs752468147; called by muse, mutect2, varscan2
- SPTBN5 | c.5171G>A p.R1724Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs199701887; called by muse, mutect2, varscan2
- SRPK2 | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 10/139 reads (7%) | catalogued as rs1402810107; called by muse, mutect2
- SRRM1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.53); catalogued as rs1266741422; called by muse, mutect2, varscan2
- SRRM4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 90/245 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs377333031; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 25/120 reads (21%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 45/136 reads (33%) | catalogued as rs748021112; called by mutect2, varscan2
- TDRKH | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 76/442 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767475622, COSV58617972; called by muse, mutect2, varscan2
- TEAD3 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1361866729; called by muse, mutect2
- TET2 | c.2511T>A p.N837K | Missense Mutation (SNP) | VAF 156/440 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs755404521; called by muse, mutect2, varscan2
- TFCP2L1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55292626; called by muse, mutect2, varscan2
- TMEM184B | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62672464; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 85/250 reads (34%) | catalogued as rs770800449; called by mutect2, varscan2
- TRAV3 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs745851436; called by muse, mutect2, varscan2
- TRIM2 | c.1087G>A p.A363T (on ENST00000437508; = p.A390T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs754123914; called by muse, mutect2, varscan2
- TRIM31 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 103/252 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs928628355; called by muse, mutect2, varscan2
- TRIM9 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 178/466 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100030317; called by muse, mutect2, varscan2
- TRPV1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903705338, COSV51518182; called by muse, mutect2, varscan2
- TSPAN33 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250376835; called by muse, mutect2
- TUBA3D | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.203); catalogued as rs745718611, COSV58312359; called by muse, mutect2, varscan2
- USP33 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs749382743, COSV62468280; called by muse, mutect2, varscan2
- VANGL2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 91/443 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100925573; called by muse, mutect2, varscan2
- VOPP1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs763022068, COSV53388039; called by muse, mutect2
- WDFY4 | c.7295G>A p.C2432Y | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1214976776; called by muse, mutect2, varscan2
- WRAP53 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 17/500 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1380952484; called by muse, mutect2
- XIRP1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 85/209 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775595813, COSV100453679; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 138/526 reads (26%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED2 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.023); catalogued as COSV51920425; called by muse, varscan2
- ZBED8 | c.894_897del p.N299Sfs*21 | Frame Shift Del (DEL) | VAF 85/211 reads (40%) | catalogued as rs1184980267; called by mutect2, pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZNF181 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101106345, COSV67627351; called by muse, mutect2
- ZNF496 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); catalogued as rs758982919, COSV54175637; called by muse, mutect2, varscan2
- ZNF512B | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs768660385, COSV53871876; called by muse, mutect2, varscan2
- ZNF697 | c.1547del p.T516Rfs*66 | Frame Shift Del (DEL) | VAF 110/349 reads (32%) | catalogued as COSV70284359; called by mutect2, pindel, varscan2
- ABCA7 | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2
- ACAP3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 251/680 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACBD3 | c.328T>A p.L110M | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTN4 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 209/550 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM21 | c.902del p.N301Ifs*4 | Frame Shift Del (DEL) | VAF 95/228 reads (42%) | called by mutect2, varscan2
- ADAM30 | c.2102T>C p.L701P | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADCY3 | c.2186A>G p.Q729R | Missense Mutation (SNP) | VAF 96/241 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.046); called by muse, varscan2
- AHRR | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AKAP9 | c.6111dup p.L2038Tfs*8 (on ENST00000359028; = p.L2006Tfs*8 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- ALKBH1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2
- AOC3 | c.957A>C p.Q319H | Missense Mutation (SNP) | VAF 137/398 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- APBA2 | c.1918-1G>T p.X640_splice | Splice Site (SNP) | VAF 52/578 reads (9%) | called by muse, mutect2
- APBB2 | c.1553A>T p.K518I (on ENST00000295974 / NM_001166050.2; = p.K519I on NM_004307.2) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- API5 | c.69+2T>C p.X23_splice | Splice Site (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- ARAP3 | c.1180del p.R394Dfs*21 | Frame Shift Del (DEL) | VAF 95/305 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4899del p.M1634* | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- ARID5A | c.1772dup p.N591Kfs*33 | Frame Shift Ins (INS) | VAF 80/278 reads (29%) | called by mutect2, pindel, varscan2
- ATM | c.3724A>G p.T1242A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- ATP13A3 | c.148A>G p.M50V | Missense Mutation (SNP) | VAF 124/353 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ATP2B1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- ATP2B4 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 59/247 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- BSCL2 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 183/530 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- C16orf89 | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CBX2 | c.977dup p.H329Afs*84 | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | called by mutect2, pindel, varscan2
- CCDC175 | c.2223G>A p.M741I | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC85C | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 124/352 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CD6 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CDH17 | c.1504del p.V502Lfs*13 | Frame Shift Del (DEL) | VAF 61/147 reads (41%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP78 | c.904A>G p.M302V | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST7 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 118/293 reads (40%) | called by muse, mutect2, varscan2
- CILP2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CLSTN1 | c.1486G>T p.E496* (on ENST00000377298 / NM_001009566.3; = p.E486* on NM_014944.4) | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CMIP | c.805C>T p.R269* (on ENST00000537098 / NM_198390.2; = p.R175* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 64/221 reads (29%) | called by muse, mutect2, varscan2
- CNOT1 | c.6575T>G p.F2192C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- COCH | c.1267T>C p.C423R (on ENST00000216361 / NM_001347720.1; = p.C358R on NM_004086.3) | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COX10 | c.1115_1116insA p.V373Cfs*92 | Frame Shift Ins (INS) | VAF 98/311 reads (32%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.1938dup p.A647Rfs*29 | Frame Shift Ins (INS) | VAF 64/211 reads (30%) | called by mutect2, pindel, varscan2
- CRHR2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CROCC | c.4692G>T p.E1564D | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- CRY2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CSMD2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- CSMD3 | c.9577C>T p.Q3193* (on ENST00000297405 / NM_001363185.1; = p.Q3024* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 116/316 reads (37%) | called by muse, mutect2, varscan2
- CYTH2 | c.1134C>A p.D378E (on ENST00000427476; = p.D377E on NM_004228.7) | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- DAAM1 | c.2663+4_2663+7del p.X888_splice | Splice Site (DEL) | VAF 24/75 reads (32%) | called by pindel, varscan2
- DBF4 | c.1122del p.V375Wfs*18 | Frame Shift Del (DEL) | VAF 10/119 reads (8%) | called by mutect2, pindel
- DCHS1 | c.2618del p.P873Qfs*5 | Frame Shift Del (DEL) | VAF 163/472 reads (35%) | called by mutect2, pindel, varscan2
- DDR2 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 175/782 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DMTF1 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 131/395 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH1 | c.11242C>T p.H3748Y | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAJB11 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DNHD1 | c.5237C>T p.P1746L | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK2 | c.144C>A p.Y48* | Nonsense Mutation (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2, varscan2
- DPH2 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- E2F8 | c.1433del p.P478Qfs*2 | Frame Shift Del (DEL) | VAF 77/283 reads (27%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.136del p.T46Hfs*24 (on ENST00000531967 / NM_001139510.1; = p.T40Hfs*24 on NM_018479.3) | Frame Shift Del (DEL) | VAF 85/263 reads (32%) | called by mutect2, pindel, varscan2
- EHF | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 68/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ELAPOR2 | c.833del p.N278Ifs*47 (on ENST00000450689 / NM_001142749.3; = p.N111Ifs*47 on NM_152748.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/124 reads (33%) | called by mutect2, pindel, varscan2
- EP400 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ERICH3 | c.2296del p.T766Rfs*23 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- ESYT1 | c.28A>G p.S10G | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFRF1 | c.128del p.N43Tfs*4 | Frame Shift Del (DEL) | VAF 53/150 reads (35%) | called by mutect2, pindel, varscan2
- EXOSC3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 70/742 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2
- FAM83E | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2
- FBN2 | c.7240G>T p.G2414C | Missense Mutation (SNP) | VAF 259/685 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FBXW7 | c.664_667delinsAG p.R223Pfs*32 (on ENST00000281708 / NM_001349798.2; = p.R143Pfs*32 on NM_018315.5) | Frame Shift Del (DEL) | VAF 53/244 reads (22%) | called by pindel, varscan2*
- FCSK | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 152/434 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FMNL1 | c.240dup p.A81Rfs*23 | Frame Shift Ins (INS) | VAF 97/347 reads (28%) | called by mutect2, pindel, varscan2
- FOXO3 | c.212del p.G71Dfs*49 | Frame Shift Del (DEL) | VAF 51/194 reads (26%) | called by mutect2, pindel, varscan2
- FSIP2 | c.20722T>C p.*6908Rext*5 | Nonstop Mutation (SNP) | VAF 22/54 reads (41%) | called by muse, varscan2
- FTO | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 145/348 reads (42%) | called by muse, mutect2, varscan2
- FZD4 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- GABRA6 | c.211T>C p.S71P | Missense Mutation (SNP) | VAF 166/462 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT7 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GLI3 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 158/427 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GON4L | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 196/906 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPAM | c.1961G>A p.G654D | Missense Mutation (SNP) | VAF 127/428 reads (30%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR75 | c.719del p.P240Lfs*2 | Frame Shift Del (DEL) | VAF 90/262 reads (34%) | called by mutect2, pindel, varscan2
- GRID2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 65/224 reads (29%) | called by mutect2, pindel, varscan2
- GSTA3 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC1 | c.14137C>T p.P4713S | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGS | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HIVEP1 | c.6791A>G p.Q2264R | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- HIVEP2 | c.1091_1092del p.T364Sfs*18 | Frame Shift Del (DEL) | VAF 50/211 reads (24%) | called by pindel, varscan2
- HOXA5 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 89/250 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HSPB1 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 194/558 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- HUWE1 | c.8121A>C p.K2707N | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.19); called by muse, mutect2
- ICAM5 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IGF1R | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL31RA | c.1706T>C p.L569P | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2
- IL3RA | c.898_901del p.N300Hfs*9 | Frame Shift Del (DEL) | VAF 121/310 reads (39%) | called by mutect2, pindel, varscan2
- IL6ST | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- INPP5F | c.2795G>A p.G932D | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.086); called by muse, mutect2
- INPPL1 | c.2337_2339del p.K779_S780delinsN | In Frame Del (DEL) | VAF 30/89 reads (34%) | called by mutect2, pindel, varscan2
- IRF2BPL | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- IRS2 | c.3965G>A p.S1322N | Missense Mutation (SNP) | VAF 138/363 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- IRX2 | c.305dup p.Y103Vfs*87 | Frame Shift Ins (INS) | VAF 52/172 reads (30%) | called by mutect2, pindel
- ITGA1 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- ITGA6 | c.276del p.P93Hfs*37 | Frame Shift Del (DEL) | VAF 212/504 reads (42%) | called by mutect2, varscan2
- ITGB5 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.009); called by muse, mutect2
- ITIH5 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.209); called by muse, mutect2
- JAK1 | c.2405_2408del p.K802Rfs*11 | Frame Shift Del (DEL) | VAF 65/212 reads (31%) | called by mutect2, pindel, varscan2
- JAM3 | c.240del p.F80Lfs*21 | Frame Shift Del (DEL) | VAF 143/416 reads (34%) | called by mutect2, pindel, varscan2
- JARID2 | c.1272del p.R425Gfs*36 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- JHY | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 19/370 reads (5%) | called by muse, mutect2
- JPH2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KCNN1 | c.1151A>G p.D384G | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- KDM4B | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF16B | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2
- KIF24 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2
- KIF5B | c.1985A>G p.E662G | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KISS1 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 194/1135 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KLHL13 | c.755G>A p.C252Y | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KLHL26 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- KLHL29 | c.1008A>C p.E336D | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KMT2B | c.4498-1G>C p.X1500_splice | Splice Site (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- LAMA1 | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 165/369 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LARP1 | c.911del p.P304Qfs*22 (on ENST00000518297 / NM_033551.3; = p.P227Qfs*22 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 97/298 reads (33%) | called by mutect2, pindel, varscan2
- LDLR | c.2530G>T p.G844C | Missense Mutation (SNP) | VAF 121/348 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMX1A | c.104G>A p.C35Y | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.997dup p.S333Ffs*12 | Frame Shift Ins (INS) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- LYST | c.8494A>G p.S2832G | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2B1 | c.2178del p.K727Rfs*39 | Frame Shift Del (DEL) | VAF 171/538 reads (32%) | called by mutect2, pindel, varscan2
- MAP1B | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 99/343 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- MDC1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MEN1 | c.881T>A p.L294Q | Missense Mutation (SNP) | VAF 217/591 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MFN2 | c.2070-7T>C | Splice Region (SNP) | VAF 50/677 reads (7%) | called by muse, mutect2
- MGRN1 | c.1283G>A p.C428Y | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- MIPEP | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MKNK2 | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 95/265 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MPHOSPH8 | c.641A>G p.K214R | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MS4A8 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 58/635 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.106); called by muse, mutect2
- NAV3 | c.7153C>A p.L2385I (on ENST00000397909 / NM_001024383.2; = p.L2363I on NM_014903.6) | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NECAB1 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 124/340 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.1462del p.R488Gfs*68 | Frame Shift Del (DEL) | VAF 75/223 reads (34%) | called by mutect2, pindel, varscan2
- NOL6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 131/428 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOS3 | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- NPR3 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUMA1 | c.25del p.A9Lfs*7 | Frame Shift Del (DEL) | VAF 111/323 reads (34%) | called by mutect2, varscan2
- NUP214 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NUP42 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | called by mutect2, pindel, varscan2
- ORC1 | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 108/341 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ORC5 | c.1029dup p.H344Tfs*25 | Frame Shift Ins (INS) | VAF 44/119 reads (37%) | called by mutect2, varscan2
- OTOG | c.5639del p.P1880Qfs*99 | Frame Shift Del (DEL) | VAF 167/498 reads (34%) | called by mutect2, pindel, varscan2
- P2RX2 | c.869C>A p.P290H (on ENST00000343948 / NM_170683.4; = p.P218H on NM_012226.5) | Missense Mutation (SNP) | VAF 123/322 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P4HA2 | c.82+2T>A p.X28_splice | Splice Site (SNP) | VAF 74/180 reads (41%) | called by muse, mutect2, varscan2
- PAPOLA | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PAPSS1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 165/473 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PBX3 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGA3 | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 235/645 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCK1 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 188/426 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.2091del p.F697Lfs*3 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- PDPR | c.2341C>A p.L781I | Missense Mutation (SNP) | VAF 101/513 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PIGB | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 66/191 reads (35%) | called by muse, mutect2, varscan2
- PIGQ | c.1802C>A p.P601H | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PIK3AP1 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 88/326 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 84/373 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- PKP2 | c.752G>C p.S251T | Missense Mutation (SNP) | VAF 163/447 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- POLR1A | c.2513C>T p.S838L | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2
- POU3F3 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 185/506 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- PPP4R3A | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 87/487 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRIMPOL | c.658del p.S220Qfs*47 | Frame Shift Del (DEL) | VAF 101/331 reads (31%) | called by mutect2, pindel, varscan2
- PRMT3 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- PRR14 | c.836del p.P279Qfs*2 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- PTK7 | c.1320dup p.P441Tfs*35 | Frame Shift Ins (INS) | VAF 59/189 reads (31%) | called by mutect2, pindel, varscan2
- PTPN1 | c.1130del p.G377Efs*27 | Frame Shift Del (DEL) | VAF 50/129 reads (39%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 132/399 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPN21 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 135/377 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPRQ | c.1045G>T p.G349* (on ENST00000616559; = p.G307* on NM_001145026.2) | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- RASAL2 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RBL1 | c.824T>G p.I275S | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RBPJ | c.663del p.F221Lfs*42 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- RFX1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.446G>A p.S149N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK2 | c.412dup p.W138Lfs*12 | Frame Shift Ins (INS) | VAF 28/74 reads (38%) | called by mutect2, varscan2
- RPE | c.620G>T p.R207I (on ENST00000359429 / NM_001318926.1; = p.R157I on NM_006916.2) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS6KA6 | c.2076T>G p.D692E | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RTL9 | c.1121C>A p.P374Q | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); called by muse, mutect2
- SAMD9L | c.4436G>A p.G1479D | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SCO2 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 237/630 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN3 | c.269T>A p.L90* | Nonsense Mutation (SNP) | VAF 106/292 reads (36%) | called by muse, mutect2, varscan2
- SETD1A | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 49/68 reads (72%) | called by mutect2, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- SGK1 | c.601T>G p.F201V | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHISA6 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 342/941 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- SHLD2 | c.1285del p.T429Hfs*3 | Frame Shift Del (DEL) | VAF 28/133 reads (21%) | called by mutect2, varscan2
- SLC8A2 | c.107G>T p.S36I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, varscan2
- SLC9A2 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCAD1 | c.1217A>G p.Q406R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 145/594 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SSC5D | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 153/403 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- STOX1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SVEP1 | c.9540del p.K3180Nfs*8 | Frame Shift Del (DEL) | VAF 96/329 reads (29%) | called by mutect2, pindel, varscan2
- SVEP1 | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SYNE1 | c.1903del p.M635Cfs*26 (on ENST00000367255 / NM_182961.4; = p.M642Cfs*26 on NM_033071.3) | Frame Shift Del (DEL) | VAF 171/522 reads (33%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5005dup p.M1669Nfs*8 | Frame Shift Ins (INS) | VAF 69/246 reads (28%) | called by mutect2, pindel, varscan2
- SYNJ2 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 279/704 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBATA | c.217A>C p.S73R | Missense Mutation (SNP) | VAF 17/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D10B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TCF19 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by mutect2, varscan2
- TCP1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.141); called by muse, mutect2
- TERB1 | c.365_368del p.S122Ffs*18 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel
- TINAG | c.296dup p.S100Vfs*5 | Frame Shift Ins (INS) | VAF 47/148 reads (32%) | called by mutect2, pindel
- TLK1 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TMEM119 | c.240del p.T81Pfs*7 | Frame Shift Del (DEL) | VAF 106/335 reads (32%) | called by mutect2, pindel, varscan2
- TMEM62 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRAV3 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TRIM41 | c.1806C>A p.H602Q | Missense Mutation (SNP) | VAF 143/411 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TRIM64C | c.68T>C p.I23T | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TRIM72 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRMT2A | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM7 | c.5260T>C p.W1754R | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC37 | c.3758del p.N1253Ifs*4 | Frame Shift Del (DEL) | VAF 88/306 reads (29%) | called by mutect2, pindel, varscan2
- TTLL5 | c.1559_1561del p.A520del | In Frame Del (DEL) | VAF 66/155 reads (43%) | called by pindel, varscan2
- TTN | c.99470del p.K33157Sfs*12 (on ENST00000591111; = p.K25733Sfs*12 on NM_003319.4) | Frame Shift Del (DEL) | VAF 76/249 reads (31%) | called by pindel, varscan2
- TTN | c.78124A>G p.K26042E (on ENST00000591111; = p.K18618E on NM_003319.4) | Missense Mutation (SNP) | VAF 77/190 reads (41%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBR5 | c.6592A>G p.R2198G | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- UQCR10 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UQCRC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- USP16 | c.868G>C p.V290L | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- USP47 | c.1205G>T p.R402M (on ENST00000399455 / NM_001372095.1; = p.R314M on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13B | c.4130G>T p.S1377I | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ZBTB1 | c.1571dup p.Q525Afs*4 | Frame Shift Ins (INS) | VAF 34/118 reads (29%) | called by mutect2, varscan2
- ZFHX3 | c.6996dup p.C2333Mfs*2 | Frame Shift Ins (INS) | VAF 67/213 reads (31%) | called by mutect2, pindel, varscan2
- ZIC5 | c.497del p.P166Lfs*165 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- ZNF292 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- ZNF449 | c.830del p.P277Qfs*8 | Frame Shift Del (DEL) | VAF 53/168 reads (32%) | called by mutect2, pindel, varscan2
- ZNFX1 | c.622C>G p.L208V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADRA2C | c.750C>A p.P250= | Silent (SNP) | VAF 28/407 reads (7%) | called by muse, mutect2
- AHNAK | c.14412G>A p.L4804= | Silent (SNP) | VAF 146/389 reads (38%) | called by muse, mutect2, varscan2
- ANHX | c.636G>A p.A212= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs565245948; called by muse, mutect2, varscan2
- ANKRD33B | c.33C>T p.G11= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs1382657596; called by muse, mutect2
- APC2 | c.6129C>T p.C2043= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs1308241401; called by muse, mutect2, varscan2
- ARHGAP21 | c.2115A>G p.L705= | Silent (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- ARHGEF17 | c.5055G>A p.E1685= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs1016884567; called by muse, mutect2
- ASB4 | c.814C>T p.L272= | Silent (SNP) | VAF 110/269 reads (41%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2526A>G p.E842= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1257678021; called by muse, mutect2, varscan2
- B3GNT9 | c.864C>T p.G288= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as rs1462443365; called by muse, mutect2, varscan2
- BAZ2A | c.5394T>C p.D1798= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as COSV51641676; called by muse, mutect2
- BDNF | c.402C>T p.R134= | Silent (SNP) | VAF 25/654 reads (4%) | catalogued as COSV59233450; called by muse, mutect2
- BRWD3 | c.5058C>T p.G1686= | Silent (SNP) | VAF 96/252 reads (38%) | catalogued as rs781010314; called by muse, mutect2, varscan2
- C10orf120 | c.549A>G p.L183= | Silent (SNP) | VAF 49/210 reads (23%) | called by muse, mutect2, varscan2
- C8B | c.660G>A p.T220= | Silent (SNP) | VAF 184/551 reads (33%) | catalogued as rs370360066; called by muse, mutect2, varscan2
- CAMK2D | c.477C>G p.G159= | Silent (SNP) | VAF 89/300 reads (30%) | called by muse, mutect2, varscan2
- CARMIL2 | c.1683G>A p.R561= | Silent (SNP) | VAF 106/281 reads (38%) | called by muse, mutect2, varscan2
- CBX8 | c.57G>A p.R19= | Silent (SNP) | VAF 86/244 reads (35%) | catalogued as rs1221350080; called by muse, mutect2, varscan2
- CD1E | c.849G>A p.L283= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- CD81 | c.396G>A p.Q132= | Silent (SNP) | VAF 217/604 reads (36%) | called by muse, mutect2, varscan2
- CDCA5 | c.396C>T p.D132= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs765815329, COSV51870761; called by muse, mutect2, varscan2
- CEBPB | c.603G>A p.A201= | Silent (SNP) | VAF 97/208 reads (47%) | catalogued as rs997116351; called by muse, mutect2, varscan2
- CEP170B | c.3321G>A p.P1107= (on ENST00000453495; = p.P1036= on NM_015005.3) | Silent (SNP) | VAF 16/272 reads (6%) | catalogued as rs571181740, COSV69023900; called by muse, mutect2
- COL23A1 | c.402C>T p.D134= | Silent (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- COL4A6 | c.1248C>T p.G416= | Silent (SNP) | VAF 105/291 reads (36%) | called by muse, mutect2, varscan2
- COL9A2 | c.1350C>T p.P450= | Silent (SNP) | VAF 177/437 reads (41%) | catalogued as COSV65622262; called by muse, mutect2, varscan2
- CTDP1 | c.2610C>T p.D870= | Silent (SNP) | VAF 40/515 reads (8%) | catalogued as rs762359718; called by muse, mutect2
- CUEDC1 | c.468C>T p.I156= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs111753270; called by muse, mutect2, varscan2
- CYSLTR1 | c.471A>G p.P157= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1204079251; called by muse, mutect2, varscan2
- DAXX | c.276G>A p.Q92= | Silent (SNP) | VAF 111/239 reads (46%) | catalogued as COSV56472142; called by muse, mutect2, varscan2
- DDB1 | c.2562G>A p.S854= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as rs771383564; called by muse, mutect2
- DLL4 | c.999T>C p.C333= | Silent (SNP) | VAF 89/218 reads (41%) | catalogued as rs773508830; called by muse, mutect2, varscan2
- DLX4 | c.27C>T p.P9= | Silent (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- DST | c.11112G>A p.V3704= (on ENST00000361203 / NM_001374722.1; = p.V1292= on NM_015548.5) | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as rs772436994; called by muse, mutect2, varscan2
- DYNC1H1 | c.10518C>T p.D3506= | Silent (SNP) | VAF 187/589 reads (32%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.1206C>T p.G402= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99552271; called by muse, mutect2
- EPB41L4B | c.1381C>A p.R461= | Silent (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- ESF1 | c.462G>A p.P154= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs916864506; called by muse, mutect2
- FTMT | c.177C>A p.T59= | Silent (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- FTMT | c.420C>T p.I140= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV58420262; called by muse, mutect2
- GAS2L3 | c.405T>C p.I135= | Silent (SNP) | VAF 109/335 reads (33%) | called by muse, mutect2, varscan2
- GPATCH4 | c.714T>C p.A238= | Silent (SNP) | VAF 120/602 reads (20%) | called by muse, mutect2, varscan2
- GRID2IP | c.2022G>A p.V674= | Silent (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- H4C1 | c.96G>A p.K32= | Silent (SNP) | VAF 87/258 reads (34%) | called by muse, mutect2, varscan2
- HCAR1 | c.657C>A p.T219= | Silent (SNP) | VAF 124/331 reads (37%) | catalogued as rs767155988; called by muse, mutect2, varscan2
- HCRTR1 | c.615C>T p.R205= | Silent (SNP) | VAF 77/176 reads (44%) | called by muse, mutect2, varscan2
- HECTD4 | c.10530G>A p.L3510= | Silent (SNP) | VAF 62/154 reads (40%) | catalogued as rs1202396543; called by muse, mutect2, varscan2
- HOXD9 | c.898C>T p.L300= | Silent (SNP) | VAF 92/274 reads (34%) | called by muse, mutect2, varscan2
- HTR1F | c.153C>T p.T51= | Silent (SNP) | VAF 149/448 reads (33%) | catalogued as COSV60390448; called by muse, mutect2, varscan2
- IBTK | c.2991C>T p.N997= | Silent (SNP) | VAF 52/135 reads (39%) | called by muse, mutect2, varscan2
- IGHE | c.381C>T p.F127= | Silent (SNP) | VAF 158/405 reads (39%) | catalogued as rs868912888; called by muse, mutect2, varscan2
- KBTBD11 | c.1644G>A p.T548= | Silent (SNP) | VAF 68/193 reads (35%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1830C>T p.F610= | Silent (SNP) | VAF 116/409 reads (28%) | catalogued as rs202015764; called by muse, mutect2, varscan2
- KIF20A | c.1173T>C p.L391= | Silent (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- KIZ | c.1248T>C p.A416= | Silent (SNP) | VAF 75/239 reads (31%) | called by muse, mutect2, varscan2
- KLHL34 | c.693C>T p.D231= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs981857318, COSV65278721; called by muse, mutect2, varscan2
- KRT39 | c.315G>A p.E105= | Silent (SNP) | VAF 108/356 reads (30%) | catalogued as COSV100842175; called by muse, mutect2, varscan2
- LAS1L | c.249A>G p.E83= | Silent (SNP) | VAF 23/174 reads (13%) | catalogued as rs1569444642; called by muse, mutect2, varscan2
- LRP5 | c.933G>A p.L311= | Silent (SNP) | VAF 14/379 reads (4%) | called by muse, mutect2
- LRWD1 | c.1596C>G p.G532= | Silent (SNP) | VAF 45/100 reads (45%) | catalogued as rs1195603578; called by muse, mutect2, varscan2
- LTBP2 | c.2856C>T p.Y952= | Silent (SNP) | VAF 240/747 reads (32%) | called by muse, mutect2, varscan2
- MACF1 | c.9255C>T p.C3085= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as COSV57111116; called by muse, mutect2
- MAP2 | c.1566C>T p.T522= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1202899945, COSV52286814; called by muse, mutect2, varscan2
- MAST4 | c.4398C>T p.H1466= (on ENST00000403625 / NM_001164664.2; = p.H1277= on NM_015183.3) | Silent (SNP) | VAF 132/317 reads (42%) | called by muse, mutect2, varscan2
- MED13 | c.5769T>C p.F1923= | Silent (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2, varscan2
- MS4A15 | c.297C>T p.H99= (on ENST00000405633 / NM_001098835.2; = p.H6= on NM_152717.3) | Silent (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- MUC5B | c.15280C>A p.R5094= | Silent (SNP) | VAF 25/477 reads (5%) | catalogued as COSV71590391; called by muse, mutect2
- MYH15 | c.1128T>C p.F376= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- NFAT5 | c.1680T>C p.S560= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs1031086836; called by muse, mutect2, varscan2
- NKX2-5 | c.300C>T p.P100= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2
- NLRP10 | c.1332C>T p.A444= | Silent (SNP) | VAF 30/374 reads (8%) | catalogued as rs1018614046, COSV60783222; called by muse, mutect2
- NPAS3 | c.2076G>A p.P692= (on ENST00000356141 / NM_001164749.2; = p.P660= on NM_022123.3) | Silent (SNP) | VAF 61/212 reads (29%) | catalogued as rs1295093051, COSV60840889; called by muse, mutect2, varscan2
- NR4A2 | c.1119C>T p.V373= | Silent (SNP) | VAF 222/581 reads (38%) | catalogued as COSV59894390; called by muse, mutect2, varscan2
- OR2L5 | c.378C>T p.C126= | Silent (SNP) | VAF 24/746 reads (3%) | called by muse, mutect2
- OR2V2 | c.63C>T p.H21= | Silent (SNP) | VAF 89/258 reads (34%) | called by muse, mutect2
- OTOF | c.5247C>T p.D1749= (on ENST00000272371 / NM_194248.3; = p.D982= on NM_004802.4) | Silent (SNP) | VAF 169/482 reads (35%) | catalogued as rs1340855486, COSV55505013; called by muse, varscan2
- OXR1 | c.1767T>C p.H589= (on ENST00000442977 / NM_001198532.1; = p.H588= on NM_018002.3) | Silent (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- PAK6 | c.141G>A p.L47= | Silent (SNP) | VAF 110/310 reads (35%) | called by muse, mutect2, varscan2
- PAOX | c.1116C>A p.A372= | Silent (SNP) | VAF 60/204 reads (29%) | catalogued as COSV53370990, COSV53372538; called by muse, varscan2
- PCDH17 | c.1518C>T p.T506= | Silent (SNP) | VAF 173/422 reads (41%) | called by muse, mutect2, varscan2
- PCDHB10 | c.1665C>T p.N555= | Silent (SNP) | VAF 146/562 reads (26%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1665C>T p.N555= | Silent (SNP) | VAF 57/1303 reads (4%) | catalogued as rs782725222, COSV50753531, COSV99176308; called by muse, mutect2
- PHF23 | c.366C>A p.P122= | Silent (SNP) | VAF 116/249 reads (47%) | catalogued as COSV50038138; called by muse, mutect2, varscan2
- PIRT | c.186C>T p.G62= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as rs555559126, COSV74119824; called by muse, mutect2, varscan2
- PKD2 | c.180G>A p.R60= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs1263674695; ClinVar: likely benign; called by muse, mutect2
- PLEC | c.12642C>T p.N4214= (on ENST00000322810 / NM_201380.4; = p.N4104= on NM_000445.5) | Silent (SNP) | VAF 191/498 reads (38%) | catalogued as rs140538836, COSV59653873; called by muse, mutect2, varscan2
- PLXNA1 | c.2322C>T p.Y774= | Silent (SNP) | VAF 141/379 reads (37%) | catalogued as rs147176760; called by muse, mutect2, varscan2
- POPDC2 | c.789C>T p.R263= | Silent (SNP) | VAF 118/336 reads (35%) | catalogued as rs1283131215; called by muse, mutect2, varscan2
- PPP1R12B | c.960G>A p.E320= | Silent (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- PRSS12 | c.1188T>C p.H396= | Silent (SNP) | VAF 47/439 reads (11%) | called by muse, mutect2, varscan2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 70/354 reads (20%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2
- PTCH1 | c.3360G>A p.E1120= | Silent (SNP) | VAF 247/602 reads (41%) | catalogued as rs1554690458; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPN18 | c.1146C>T p.S382= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- RALBP1 | c.900G>A p.V300= | Silent (SNP) | VAF 96/234 reads (41%) | called by muse, mutect2, varscan2
- RALY | c.468G>A p.R156= (on ENST00000246194 / NM_016732.3; = p.R140= on NM_007367.4) | Silent (SNP) | VAF 78/253 reads (31%) | called by muse, mutect2, varscan2
- RBM15 | c.1221G>A p.R407= | Silent (SNP) | VAF 102/270 reads (38%) | catalogued as rs777680641; called by muse, mutect2, varscan2
- RBMXL3 | c.435G>A p.P145= | Silent (SNP) | VAF 8/222 reads (4%) | catalogued as rs1556556536; called by muse, mutect2
- RPS6KC1 | c.684C>T p.G228= | Silent (SNP) | VAF 18/460 reads (4%) | called by muse, mutect2
- SETBP1 | c.819G>A p.T273= | Silent (SNP) | VAF 110/370 reads (30%) | catalogued as rs772700161, COSV56336632; called by muse, mutect2, varscan2
- SETBP1 | c.1431A>G p.S477= | Silent (SNP) | VAF 286/746 reads (38%) | called by muse, varscan2
- SLC25A46 | c.192C>T p.Y64= | Silent (SNP) | VAF 30/513 reads (6%) | catalogued as rs1388921249; called by muse, mutect2
- SLC4A7 | c.3234G>A p.P1078= | Silent (SNP) | VAF 89/291 reads (31%) | catalogued as rs747613260, COSV55403551; called by muse, mutect2, varscan2
- SLC5A9 | c.651G>A p.T217= | Silent (SNP) | VAF 108/303 reads (36%) | catalogued as rs61730938, COSV52581784, COSV99361310; called by muse, mutect2, varscan2
- SNAP23 | c.255C>T p.C85= | Silent (SNP) | VAF 27/62 reads (44%) | called by muse, mutect2, varscan2
- SORBS1 | c.1173A>T p.S391= (on ENST00000361941 / NM_001034954.2; = p.S227= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- SPEG | c.3678C>T p.H1226= | Silent (SNP) | VAF 147/392 reads (38%) | catalogued as rs1388099213; called by muse, mutect2, varscan2
- SSTR4 | c.378C>T p.D126= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs770914493, COSV54796826; called by muse, mutect2, varscan2
- STRA6 | c.417T>C p.T139= | Silent (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2
- TAPBPL | c.685C>T p.L229= | Silent (SNP) | VAF 174/457 reads (38%) | catalogued as rs1161833645; called by muse, mutect2, varscan2
- TBC1D2B | c.45C>T p.G15= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1355981887; called by muse, mutect2
- TECTA | c.285C>T p.F95= | Silent (SNP) | VAF 109/303 reads (36%) | catalogued as rs775584376, COSV50817729; called by muse, mutect2, varscan2
- TEX38 | c.216A>C p.R72= | Silent (SNP) | VAF 100/235 reads (43%) | called by muse, mutect2, varscan2
- TFRC | c.2094A>G p.R698= | Silent (SNP) | VAF 108/287 reads (38%) | called by muse, mutect2, varscan2
- THEMIS2 | c.1866G>A p.R622= | Silent (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.762C>T p.P254= | Silent (SNP) | VAF 84/244 reads (34%) | catalogued as rs774631193; called by muse, mutect2, varscan2
- TRNAU1AP | c.849C>A p.I283= | Silent (SNP) | VAF 52/134 reads (39%) | called by muse, mutect2, varscan2
- TRPS1 | c.2178C>T p.G726= (on ENST00000220888 / NM_001330599.2; = p.G739= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/380 reads (11%) | catalogued as COSV99631792; called by muse, mutect2, varscan2
- TTBK2 | c.3585A>G p.S1195= | Silent (SNP) | VAF 30/448 reads (7%) | called by muse, mutect2
- TTN | c.73296A>G p.V24432= (on ENST00000591111; = p.V17008= on NM_003319.4) | Silent (SNP) | VAF 103/273 reads (38%) | catalogued as rs761647014; called by muse, mutect2, varscan2
- UPB1 | c.852C>T p.C284= | Silent (SNP) | VAF 219/611 reads (36%) | catalogued as rs781196303, COSV58116158; called by muse, mutect2, varscan2
- URB1 | c.3586C>T p.L1196= | Silent (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- USH2A | c.8826C>T p.D2942= | Silent (SNP) | VAF 79/418 reads (19%) | catalogued as rs775823422; called by muse, mutect2, varscan2
- VEGFD | c.438C>T p.C146= | Silent (SNP) | VAF 89/212 reads (42%) | called by muse, mutect2, varscan2
- VGLL2 | c.666G>A p.P222= | Silent (SNP) | VAF 169/478 reads (35%) | called by muse, mutect2, varscan2
- WDR90 | c.2143C>T p.L715= | Silent (SNP) | VAF 170/444 reads (38%) | called by muse, mutect2, varscan2
- ZBTB16 | c.31C>T p.L11= | Silent (SNP) | VAF 22/386 reads (6%) | catalogued as rs749597976; called by muse, mutect2
- ZBTB16 | c.1386C>T p.V462= | Silent (SNP) | VAF 56/610 reads (9%) | called by muse, mutect2
- ZNF544 | c.1680C>T p.N560= | Silent (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- ZNF644 | c.1824G>A p.L608= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- ZNF850 | c.723T>C p.I241= | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444462 G>A | 5'Flank (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-542-14097C>T | Intron (SNP) | VAF 101/233 reads (43%) | catalogued as rs1190788629; called by muse, mutect2, varscan2
- ADAM1A | n.1368C>T | RNA (SNP) | VAF 92/290 reads (32%) | called by muse, mutect2, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 15/178 reads (8%) | catalogued as rs779843196; called by pindel, varscan2*
- AK9 | c.1254+19_1254+22del | Intron (DEL) | VAF 9/75 reads (12%) | catalogued as rs770626634; called by mutect2, pindel, varscan2*
- ANXA8 | c.*181C>T | 3'UTR (SNP) | VAF 172/962 reads (18%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620943 G>A | 3'Flank (SNP) | VAF 162/487 reads (33%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11575C>A | Intron (SNP) | VAF 66/190 reads (35%) | called by muse, mutect2, varscan2
- ARL13B | c.130+613del | Intron (DEL) | VAF 25/88 reads (28%) | called by mutect2, pindel, varscan2
- B3GALNT2 | c.113-1407G>A | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as rs1383985581; called by muse, mutect2, varscan2
- BMP1 | c.731-280C>A | Intron (SNP) | VAF 30/454 reads (7%) | called by muse, mutect2
- CACNB1 | c.1332+23G>A | Intron (SNP) | VAF 104/277 reads (38%) | called by muse, mutect2, varscan2
- CDK5RAP3 | chr17:47971080 C>A | 5'Flank (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
- CFAP52 | c.71-1461G>A | Intron (SNP) | VAF 32/104 reads (31%) | catalogued as rs867168009; called by muse, mutect2, varscan2
- CFAP69 | c.-13G>C | 5'UTR (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- COQ8A | c.*34A>T | 3'UTR (SNP) | VAF 88/502 reads (18%) | called by muse, mutect2, varscan2
- CTDSP1 | c.67+557G>A | Intron (SNP) | VAF 134/361 reads (37%) | catalogued as rs910857141; called by muse, mutect2, varscan2
- DDX11 | c.638+900G>A | Intron (SNP) | VAF 164/500 reads (33%) | catalogued as rs1215835829; called by muse, mutect2, varscan2
- DOK6 | c.-36C>T | 5'UTR (SNP) | VAF 100/328 reads (30%) | catalogued as rs1218006178, COSV101235037; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-45T>G | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- EGFL6 | c.*50del | 3'UTR (DEL) | VAF 31/104 reads (30%) | catalogued as rs1446348498; called by mutect2, pindel, varscan2
- EMC10 | c.679-266C>G | Intron (SNP) | VAF 57/172 reads (33%) | catalogued as rs779918120, COSV58541974; called by muse, mutect2, varscan2
- ENAH | c.803-282del | Intron (DEL) | VAF 55/280 reads (20%) | called by mutect2, pindel, varscan2
- FAM181A | c.100-576C>T | Intron (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- FAS | c.*589C>T | 3'UTR (SNP) | VAF 71/262 reads (27%) | called by muse, mutect2, varscan2
- GLYCTK | c.-47G>C | 5'UTR (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- GNAS | c.2068+240C>T | Intron (SNP) | VAF 94/269 reads (35%) | catalogued as rs967732544; called by muse, mutect2, varscan2
- HDAC5 | c.*69A>C | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- HEXD | c.*44del | 3'UTR (DEL) | VAF 89/270 reads (33%) | catalogued as rs751615819; called by mutect2, pindel, varscan2
- JAKMIP2 | c.2413-2775T>C | Intron (SNP) | VAF 99/236 reads (42%) | called by muse, mutect2, varscan2
- KCNC3 | c.*1385C>T | 3'UTR (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- KDM4C | c.2994+116del | Intron (DEL) | VAF 70/194 reads (36%) | catalogued as COSV67183745; called by mutect2, varscan2
- L3MBTL1 | c.1193-30C>T | Intron (SNP) | VAF 89/281 reads (32%) | catalogued as rs374464014; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331751 ins C | 5'Flank (INS) | VAF 27/204 reads (13%) | called by mutect2, pindel, varscan2
- LRRC8D | c.-141C>T | 5'UTR (SNP) | VAF 63/206 reads (31%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+106G>A | Intron (SNP) | VAF 23/65 reads (35%) | catalogued as rs767804788; called by muse, mutect2, varscan2
- MDFIC | c.-7G>A | 5'UTR (SNP) | VAF 105/277 reads (38%) | catalogued as rs930922489; called by muse, mutect2, varscan2
- MS4A6A | c.651+10C>T | Intron (SNP) | VAF 110/282 reads (39%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40421242 del A | 3'Flank (DEL) | VAF 13/42 reads (31%) | catalogued as rs746639059; called by mutect2, pindel, varscan2
- MUCL3 | c.946+868A>G | Intron (SNP) | VAF 84/359 reads (23%) | catalogued as rs1305952989, COSV58516256; called by muse, varscan2
- MYH16 | n.2911C>A | RNA (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- NAPA | c.561+148del | Intron (DEL) | VAF 42/116 reads (36%) | catalogued as rs1349876274; called by mutect2, varscan2
- NEK7 | c.198+3306del | Intron (DEL) | VAF 19/82 reads (23%) | catalogued as rs749732874; called by mutect2, pindel, varscan2
- NLRC5 | c.4154+205G>T | Intron (SNP) | VAF 80/206 reads (39%) | catalogued as rs1295311548; called by muse, mutect2, varscan2
- NRIP3 | c.*612G>A | 3'UTR (SNP) | VAF 47/144 reads (33%) | catalogued as rs1339089593, COSV100487129; called by muse, mutect2, varscan2
- OGFOD1 | c.301-20del | Intron (DEL) | VAF 56/156 reads (36%) | catalogued as rs771823733; called by mutect2, varscan2
- OR7A2P | n.362G>A | RNA (SNP) | VAF 20/246 reads (8%) | catalogued as rs528570028; called by muse, mutect2
- PADI1 | c.*96dup | 3'UTR (INS) | VAF 207/702 reads (29%) | called by mutect2, pindel, varscan2
- PAPSS2 | c.-26C>T | 5'UTR (SNP) | VAF 38/768 reads (5%) | called by muse, mutect2
- PCSK4 | c.1391+15C>T | Intron (SNP) | VAF 52/142 reads (37%) | catalogued as rs539574874; called by muse, mutect2
- PHYKPL | c.59+17C>T | Intron (SNP) | VAF 61/159 reads (38%) | catalogued as rs749198645; called by muse, mutect2, varscan2
- PI4KAP2 | n.2831C>A | RNA (SNP) | VAF 96/246 reads (39%) | called by muse, varscan2
- PITRM1 | c.2646-904C>T | Intron (SNP) | VAF 54/199 reads (27%) | catalogued as rs919528512; called by muse, mutect2, varscan2
- PLEKHD1 | c.243+99C>T | Intron (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2
- POLM | c.714+75C>A | Intron (SNP) | VAF 42/112 reads (38%) | called by muse, varscan2
- POPDC2 | c.1009+84del | Intron (DEL) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- PRKCB | c.-5G>A | 5'UTR (SNP) | VAF 136/320 reads (43%) | called by muse, mutect2, varscan2
- PRRC2C | c.8199+1071G>A | Intron (SNP) | VAF 123/561 reads (22%) | called by muse, mutect2, varscan2
- PUS10 | c.126+907C>T | Intron (SNP) | VAF 82/242 reads (34%) | called by muse, mutect2, varscan2
- PYCARD | c.275-9T>C | Intron (SNP) | VAF 14/376 reads (4%) | called by muse, mutect2
- RAB26 | c.307-380T>G | Intron (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- RNF14 | chr5:141991892 G>A | 3'Flank (SNP) | VAF 81/217 reads (37%) | called by muse, mutect2, varscan2
- RNF220 | c.1630-10C>G | Intron (SNP) | VAF 75/373 reads (20%) | called by muse, mutect2, varscan2
- RPL28 | c.205+160_205+162del | Intron (DEL) | VAF 32/125 reads (26%) | catalogued as rs750063282; called by mutect2, pindel, varscan2
- SCN4B | c.*317G>A | 3'UTR (SNP) | VAF 201/592 reads (34%) | catalogued as rs1431822176; called by muse, mutect2, varscan2
- SLAMF8 | chr1:159837959 C>T | 3'Flank (SNP) | VAF 113/657 reads (17%) | called by muse, mutect2, varscan2
- SNAP47 | c.1249-4721G>A | Intron (SNP) | VAF 72/381 reads (19%) | catalogued as rs566590122; called by muse, mutect2, varscan2
- SNW1 | c.1413-30T>A | Intron (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-33dup | 5'UTR (INS) | VAF 48/144 reads (33%) | called by mutect2, pindel, varscan2
- STAB1 | c.4364-40del | Intron (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- TPRXL | n.752C>T | RNA (SNP) | VAF 34/256 reads (13%) | catalogued as rs192562800; called by muse, varscan2
- UBR2 | c.1281+157G>A | Intron (SNP) | VAF 55/157 reads (35%) | catalogued as rs978399522; called by muse, mutect2, varscan2
- VPS28 | c.548+54C>A | Intron (SNP) | VAF 99/228 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-20del | Intron (DEL) | VAF 25/85 reads (29%) | catalogued as rs767083235; called by mutect2, varscan2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 38/112 reads (34%) | catalogued as rs751858242; called by mutect2, varscan2
- ZNF252P | n.245+3153del | Intron (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ZRANB3 | c.1206+399del | Intron (DEL) | VAF 50/167 reads (30%) | called by mutect2, pindel, varscan2
